Somatic mutation profile of tumor specimen HCM-BROD-0830-C71-02A (aliquot HCM-BROD-0830-C71-02A-11D-A85K-36) from HCMI case HCM-BROD-0830-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.4 years (21,323 days).
Specimen HCM-BROD-0830-C71-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5302db9d-34b5-4b1a-8249-964566aca957.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0830-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0830-C71-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5621a919-5217-49b5-b596-8eee68fb0a1e

The open-access MAF lists 151 somatic variants for this specimen: 120 protein-altering or splice-affecting, 28 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 28, Frame Shift Del 17, Nonsense Mutation 5, In Frame Del 3, Intron 3, Splice Region 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 281/361 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ADCY1 | c.1020G>A p.T340= | Splice Region (SNP) | VAF 68/390 reads (17%) | catalogued as rs775492975, COSV99812760; called by muse, mutect2, varscan2
- ANKRD11 | c.4925C>T p.P1642L | Missense Mutation (SNP) | VAF 112/423 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs753598147; called by muse, mutect2, varscan2
- AP2B1 | c.766del p.V256Cfs*5 | Frame Shift Del (DEL) | VAF 60/351 reads (17%) | catalogued as COSV51998308; called by mutect2, pindel, varscan2
- ARHGEF5 | c.778C>G p.Q260E | Missense Mutation (SNP) | VAF 97/523 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as rs755891405; called by muse, mutect2, varscan2
- ASPM | c.5008G>A p.V1670I | Missense Mutation (SNP) | VAF 79/338 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as rs765920262, COSV99661494; called by muse, mutect2, varscan2
- ATP4A | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 231/831 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370650252; called by muse, mutect2, varscan2
- B3GALT6 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 174/831 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs1267101770; called by muse, mutect2, varscan2
- BCLAF1 | c.683G>T p.S228I | Missense Mutation (SNP) | VAF 51/444 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV100786708; called by muse, mutect2, varscan2
- C1orf141 | c.940C>G p.L314V | Missense Mutation (SNP) | VAF 58/322 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.349); catalogued as rs776456150; called by muse, mutect2, varscan2
- CBL | c.1151G>A p.C384Y | Missense Mutation (SNP) | VAF 14/343 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs985412813, COSV50633156; called by muse, mutect2
- CCBE1 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 139/349 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768229052, COSV101232777, COSV67949152; called by muse, mutect2, varscan2
- CDCA5 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 135/337 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs774757594; called by muse, mutect2, varscan2
- CHPF | c.1412C>T p.A471V | Missense Mutation (SNP) | VAF 297/588 reads (51%) | SIFT tolerated (0.5); PolyPhen benign (0.059); catalogued as rs1388942317; called by muse, mutect2, varscan2
- CLPS | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 54/357 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs140627661; called by muse, mutect2, varscan2
- COL21A1 | c.2042C>A p.S681Y | Missense Mutation (SNP) | VAF 62/255 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.273); catalogued as COSV55174299; called by muse, mutect2, varscan2
- CPXCR1 | c.547C>A p.H183N | Missense Mutation (SNP) | VAF 19/435 reads (4%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV52162836; called by muse, mutect2
- CYP2J2 | c.758A>G p.K253R | Missense Mutation (SNP) | VAF 164/438 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as rs888270915, COSV64605835; called by muse, mutect2, varscan2
- FBXO7 | c.1183C>A p.L395M | Missense Mutation (SNP) | VAF 51/231 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV56678642; called by muse, mutect2, varscan2
- FCAMR | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 159/301 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs942157612, COSV100249171; called by muse, mutect2, varscan2
- FLG | c.309G>T p.K103N | Missense Mutation (SNP) | VAF 194/331 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs201066653; called by mutect2, varscan2
- FREM3 | c.5944G>A p.V1982I | Missense Mutation (SNP) | VAF 72/222 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.17); catalogued as rs954270962, COSV61682060; called by muse, mutect2, varscan2
- GREB1 | c.5273G>A p.R1758Q | Missense Mutation (SNP) | VAF 150/435 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs760722393; called by muse, mutect2, varscan2
- GRIN2A | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 102/383 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs367543123, COSV58021077; ClinVar: not provided; called by muse, mutect2, varscan2
- GRM4 | c.2246C>T p.S749L | Missense Mutation (SNP) | VAF 198/409 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs747427620, COSV65213574; called by muse, mutect2, varscan2
- HERC1 | c.7309G>A p.A2437T | Missense Mutation (SNP) | VAF 36/251 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs367997811; called by muse, mutect2, varscan2
- HUNK | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 207/445 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs754441068, COSV54226102; called by muse, mutect2, varscan2
- IGHV3-13 | c.128C>G p.A43G | Missense Mutation (SNP) | VAF 111/429 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.48); catalogued as rs1555437235; called by muse, mutect2, varscan2
- KRTAP4-7 | c.131G>C p.C44S | Missense Mutation (SNP) | VAF 564/826 reads (68%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV66951930; called by muse, varscan2
- LRRC9 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 66/280 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs1009522324; called by muse, mutect2, varscan2
- MAD1L1 | c.1750G>A p.V584I | Missense Mutation (SNP) | VAF 270/684 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs756134237; called by muse, varscan2
- MC4R | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 122/368 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as rs758426526, CM035970, COSV55351515; called by muse, mutect2, varscan2
- NFATC2 | c.1791C>G p.I597M | Missense Mutation (SNP) | VAF 90/428 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65356363; called by muse, mutect2, varscan2
- NOS1 | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 226/440 reads (51%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs1051778934, COSV57623027; called by muse, mutect2, varscan2
- NR0B1 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 94/503 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.628); catalogued as rs104894888, CM940013; called by muse, mutect2, varscan2
- NRXN3 | c.577G>T p.G193C | Missense Mutation (SNP) | VAF 64/360 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV73587775; called by muse, mutect2, varscan2
- OR2A14 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 147/430 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs761628504, COSV101376503; called by muse, mutect2, varscan2
- PARVB | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 101/317 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1223689233; called by muse, mutect2, varscan2
- PCDHGB2 | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 194/393 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV53986548; called by muse, mutect2, varscan2
- PKN3 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 102/518 reads (20%) | catalogued as rs771744489; called by muse, mutect2, varscan2
- PLEKHG4B | c.1394C>T p.A465V (on ENST00000283426; = p.A821V on NM_052909.5) | Missense Mutation (SNP) | VAF 143/359 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.36); catalogued as rs376874976; called by muse, mutect2, varscan2
- PNMA6F | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 228/563 reads (40%) | SIFT tolerated (0.44); catalogued as rs193001516; called by muse, mutect2, varscan2
- RAB40AL | c.98G>A p.S33N | Missense Mutation (SNP) | VAF 139/418 reads (33%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.92); catalogued as rs747476866; called by muse, mutect2, varscan2
- RALYL | c.76G>A p.G26S | Missense Mutation (SNP) | VAF 73/500 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72818856; called by muse, mutect2, varscan2
- RTKN | c.1123C>G p.L375V (on ENST00000272430 / NM_001015055.2; = p.L362V on NM_033046.2) | Missense Mutation (SNP) | VAF 108/321 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs754600529; called by muse, mutect2, varscan2
- SDE2 | c.952del p.E318Rfs*13 | Frame Shift Del (DEL) | VAF 84/612 reads (14%) | catalogued as COSV55251262; called by mutect2, pindel, varscan2
- SEMA3E | c.336G>A p.A112= | Splice Region (SNP) | VAF 36/329 reads (11%) | catalogued as rs770979660, COSV57097655; called by muse, mutect2, varscan2
- SGCZ | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 154/412 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372855106; called by muse, varscan2
- SLC12A3 | c.1189G>A p.V397M | Missense Mutation (SNP) | VAF 89/299 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.746); catalogued as rs387907472; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNAP91 | c.1219G>C p.E407Q | Missense Mutation (SNP) | VAF 85/365 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.444); catalogued as COSV52130428; called by muse, mutect2, varscan2
- SVIL | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 201/313 reads (64%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs373559551; called by muse, mutect2, varscan2
- TEKT4 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 227/566 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs782314314, COSV54623601; called by muse, mutect2, varscan2
- TESC | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 192/585 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.108); catalogued as rs1294729983; called by muse, mutect2, varscan2
- TXLNB | c.793A>G p.S265G | Missense Mutation (SNP) | VAF 186/433 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs375239112; called by muse, mutect2, varscan2
- UBASH3A | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 88/315 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.42); catalogued as rs749296137; called by muse, mutect2, varscan2
- VPS13A | c.8756G>C p.G2919A | Missense Mutation (SNP) | VAF 86/286 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1487147914; called by muse, mutect2, varscan2
- VSTM2B | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 126/392 reads (32%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs761971447, COSV100139189, COSV59259691; called by muse, mutect2, varscan2
- VSX2 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 143/589 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as rs1205109093; called by muse, mutect2, varscan2
- WDR70 | c.1726C>T p.R576* | Nonsense Mutation (SNP) | VAF 41/231 reads (18%) | catalogued as rs916615406; called by muse, mutect2, varscan2
- ABCB5 | c.1932C>G p.N644K (on ENST00000404938 / NM_001163941.2; = p.N199K on NM_178559.6) | Missense Mutation (SNP) | VAF 158/433 reads (36%) | SIFT tolerated (0.84); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANXA8L1 | c.256C>A p.L86I | Missense Mutation (SNP) | VAF 171/530 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- ATF7 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 30/331 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATF7 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 29/328 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BCL11A | c.524del p.P175Rfs*9 (on ENST00000335712 / NM_001365609.1; = p.P209Rfs*9 on NM_018014.4) | Frame Shift Del (DEL) | VAF 127/456 reads (28%) | called by mutect2, pindel, varscan2
- BICDL2 | c.952_956del p.T318Dfs*50 | Frame Shift Del (DEL) | VAF 62/402 reads (15%) | called by mutect2, pindel, varscan2
- C9orf152 | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.689); called by muse, mutect2
- CCDC112 | c.55_58del p.E19Ifs*4 | Frame Shift Del (DEL) | VAF 28/248 reads (11%) | called by mutect2, pindel, varscan2
- CDH6 | c.1200_1202del p.T401del | In Frame Del (DEL) | VAF 157/438 reads (36%) | called by pindel, varscan2
- CDK5RAP2 | c.3127C>T p.Q1043* | Nonsense Mutation (SNP) | VAF 67/291 reads (23%) | called by muse, mutect2, varscan2
- CEACAM5 | c.629C>T p.T210I | Missense Mutation (SNP) | VAF 219/626 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- CENPE | c.543G>T p.W181C | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CERS6 | c.770_787del p.Q257_L262del | In Frame Del (DEL) | VAF 40/334 reads (12%) | called by mutect2, pindel, varscan2
- CFAP57 | c.888_889del p.C297Ffs*11 | Frame Shift Del (DEL) | VAF 92/421 reads (22%) | called by mutect2, pindel, varscan2
- CMTM7 | c.160G>C p.V54L | Missense Mutation (SNP) | VAF 50/342 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EPHA1 | c.2452G>C p.E818Q | Missense Mutation (SNP) | VAF 183/577 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT1 | c.1678A>T p.N560Y | Missense Mutation (SNP) | VAF 113/302 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- FFAR3 | c.299A>G p.Y100C | Missense Mutation (SNP) | VAF 120/605 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- FRMD5 | c.417C>A p.Y139* | Nonsense Mutation (SNP) | VAF 87/193 reads (45%) | called by muse, mutect2, varscan2
- GEMIN5 | c.376G>C p.V126L | Missense Mutation (SNP) | VAF 115/350 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- GSPT1 | c.1168G>A p.G390R (on ENST00000420576 / NM_001130007.2; = p.G528R on NM_002094.4) | Missense Mutation (SNP) | VAF 58/274 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- HAUS6 | c.1084C>G p.L362V | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IRAK4 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 78/403 reads (19%) | called by muse, mutect2, varscan2
- KCTD3 | c.2168A>G p.D723G | Missense Mutation (SNP) | VAF 214/414 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KLK2 | c.428C>A p.T143N | Missense Mutation (SNP) | VAF 216/680 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- KNL1 | c.2412_2415del p.E804Dfs*9 (on ENST00000346991 / NM_170589.5; = p.E778Dfs*9 on NM_144508.5) | Frame Shift Del (DEL) | VAF 71/283 reads (25%) | called by mutect2, pindel, varscan2
- LIMA1 | c.1984A>C p.T662P | Missense Mutation (SNP) | VAF 178/513 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- MEF2A | c.1008_1009+33del p.X336_splice (on ENST00000557942 / NM_001319206.2; = p.X330_splice on NM_005587.4 and 8 other RefSeq transcripts) | Splice Site (DEL) | VAF 74/235 reads (31%) | called by mutect2, pindel, varscan2
- MSGN1 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 98/439 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- MTMR14 | c.535del p.E179Rfs*36 | Frame Shift Del (DEL) | VAF 63/374 reads (17%) | called by mutect2, pindel, varscan2
- NRXN3 | c.578G>T p.G193V | Missense Mutation (SNP) | VAF 64/358 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- OR4D1 | c.670A>T p.M224L | Missense Mutation (SNP) | VAF 335/414 reads (81%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OR51A2 | c.552G>T p.Q184H | Missense Mutation (SNP) | VAF 118/463 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.33); called by muse, varscan2
- OXCT2 | c.548T>C p.M183T | Missense Mutation (SNP) | VAF 52/431 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- PGM2 | c.694G>C p.D232H | Missense Mutation (SNP) | VAF 146/295 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- PID1 | c.11C>G p.P4R | Missense Mutation (SNP) | VAF 28/560 reads (5%) | SIFT tolerated, low confidence (0.32); PolyPhen probably damaging (0.946); called by muse, mutect2
- PKHD1L1 | c.12380T>A p.L4127H | Missense Mutation (SNP) | VAF 68/395 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- PLEKHG2 | c.754_763del p.K252Rfs*19 | Frame Shift Del (DEL) | VAF 74/428 reads (17%) | called by mutect2, pindel, varscan2
- PRAMEF12 | c.463A>G p.N155D | Missense Mutation (SNP) | VAF 112/374 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PTPN21 | c.1988_1989del p.E663Gfs*35 | Frame Shift Del (DEL) | VAF 138/680 reads (20%) | called by pindel, varscan2
- RNGTT | c.193G>T p.V65L | Missense Mutation (SNP) | VAF 53/209 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- ROR2 | c.1024del p.L342Cfs*103 | Frame Shift Del (DEL) | VAF 118/608 reads (19%) | called by mutect2, pindel, varscan2
- SEMG2 | c.775_793del p.E259Rfs*66 | Frame Shift Del (DEL) | VAF 106/411 reads (26%) | called by mutect2, pindel, varscan2
- SKIL | c.38del p.G13Afs*6 | Frame Shift Del (DEL) | VAF 73/370 reads (20%) | called by mutect2, pindel, varscan2
- SMC1B | c.3275C>T p.A1092V | Missense Mutation (SNP) | VAF 46/262 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- SRSF4 | c.763A>G p.S255G | Missense Mutation (SNP) | VAF 59/632 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2
- SUPT16H | c.1642_1644del p.P548del | In Frame Del (DEL) | VAF 68/283 reads (24%) | called by mutect2, pindel, varscan2
- TCEAL1 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 117/386 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCEANC2 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 68/323 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- TERB1 | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 74/147 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- TERF2 | c.107del p.G36Afs*123 | Frame Shift Del (DEL) | VAF 118/620 reads (19%) | called by mutect2, pindel, varscan2
- TGFBI | c.1499C>A p.P500H | Missense Mutation (SNP) | VAF 120/438 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TP53I3 | c.582del p.E195Rfs*8 | Frame Shift Del (DEL) | VAF 93/333 reads (28%) | called by mutect2, pindel, varscan2
- TRIM64B | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 28/323 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRMT11 | c.361_362del p.Q121Rfs*11 | Frame Shift Del (DEL) | VAF 16/142 reads (11%) | called by pindel, varscan2
- TTYH3 | c.1040del p.Q347Rfs*4 | Frame Shift Del (DEL) | VAF 101/605 reads (17%) | called by mutect2, pindel, varscan2
- TWF1 | c.145T>A p.W49R | Missense Mutation (SNP) | VAF 49/231 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UNC13A | c.270G>A p.E90= | Splice Region (SNP) | VAF 107/397 reads (27%) | called by muse, mutect2, varscan2
- URGCP | c.2733G>T p.R911S (on ENST00000453200 / NM_001077663.3; = p.R902S on NM_017920.4) | Missense Mutation (SNP) | VAF 71/476 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- USP26 | c.2445A>T p.R815S | Missense Mutation (SNP) | VAF 129/402 reads (32%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- ZNF721 | c.2671A>G p.R891G (on ENST00000338977; = p.R903G on NM_133474.4) | Missense Mutation (SNP) | VAF 131/264 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ACTN4 | c.633G>A p.E211= | Silent (SNP) | VAF 168/501 reads (34%) | called by muse, mutect2, varscan2
- ADAM28 | c.882G>A p.Q294= | Silent (SNP) | VAF 24/240 reads (10%) | called by muse, mutect2
- BDKRB2 | c.693G>T p.V231= | Silent (SNP) | VAF 219/457 reads (48%) | called by muse, mutect2, varscan2
- CCDC120 | c.381G>A p.A127= | Silent (SNP) | VAF 195/508 reads (38%) | called by muse, mutect2, varscan2
- GRIK1 | c.1713C>G p.L571= | Silent (SNP) | VAF 159/457 reads (35%) | called by muse, mutect2, varscan2
- HSPH1 | c.1602C>T p.D534= | Silent (SNP) | VAF 104/240 reads (43%) | called by muse, mutect2, varscan2
- HYDIN | c.11322G>A p.T3774= | Silent (SNP) | VAF 63/203 reads (31%) | catalogued as rs529795965; called by muse, varscan2
- KMT2D | c.14226C>T p.P4742= | Silent (SNP) | VAF 203/522 reads (39%) | catalogued as rs1229281996; called by muse, mutect2, varscan2
- LANCL3 | c.1182C>T p.G394= | Silent (SNP) | VAF 11/404 reads (3%) | called by muse, mutect2
- LYPD5 | c.384G>A p.P128= (on ENST00000377950 / NM_001031749.3; = p.P85= on NM_182573.2) | Silent (SNP) | VAF 45/428 reads (11%) | catalogued as rs371523113; called by muse, mutect2, varscan2
- MAP3K19 | c.3822C>T p.A1274= | Silent (SNP) | VAF 96/264 reads (36%) | catalogued as rs777421257, COSV100208380; called by muse, mutect2, varscan2
- MATN2 | c.2868A>G p.R956= | Silent (SNP) | VAF 101/330 reads (31%) | called by muse, mutect2, varscan2
- MYBPC1 | c.753C>T p.S251= (on ENST00000550270 / NM_206820.2; = p.S276= on NM_002465.4) | Silent (SNP) | VAF 45/254 reads (18%) | catalogued as rs753935679, COSV100637708; called by muse, mutect2, varscan2
- NAIF1 | c.945G>A p.Q315= | Silent (SNP) | VAF 112/376 reads (30%) | called by muse, varscan2
- NKX6-3 | c.60G>A p.P20= | Silent (SNP) | VAF 131/389 reads (34%) | catalogued as rs1315904214; called by muse, mutect2, varscan2
- NLRP12 | c.2838G>A p.L946= | Silent (SNP) | VAF 142/567 reads (25%) | called by muse, mutect2, varscan2
- NOTCH3 | c.6303C>A p.P2101= | Silent (SNP) | VAF 143/907 reads (16%) | called by muse, mutect2, varscan2
- PCSK4 | c.711C>T p.T237= | Silent (SNP) | VAF 62/668 reads (9%) | catalogued as rs146245320; called by muse, mutect2
- RFX6 | c.2679T>C p.Y893= | Silent (SNP) | VAF 13/400 reads (3%) | called by muse, mutect2
- SATB1 | c.81A>G p.P27= | Silent (SNP) | VAF 200/478 reads (42%) | catalogued as rs748444125, COSV58667363; called by muse, mutect2, varscan2
- SNAP91 | c.1218A>C p.P406= | Silent (SNP) | VAF 84/360 reads (23%) | called by muse, mutect2, varscan2
- TJP3 | c.1275G>A p.Q425= | Silent (SNP) | VAF 117/532 reads (22%) | called by muse, mutect2, varscan2
- TMEM132C | c.3174C>A p.T1058= | Silent (SNP) | VAF 174/630 reads (28%) | called by muse, mutect2, varscan2
- TMEM202 | c.333A>C p.P111= | Silent (SNP) | VAF 9/241 reads (4%) | called by muse, mutect2
- TNRC6A | c.1428T>A p.P476= | Silent (SNP) | VAF 62/288 reads (22%) | called by muse, mutect2, varscan2
- TRIL | c.2061C>T p.A687= | Silent (SNP) | VAF 54/972 reads (6%) | catalogued as rs977373367; called by muse, mutect2
- UGT2B4 | c.303A>G p.P101= | Silent (SNP) | VAF 80/286 reads (28%) | called by muse, mutect2, varscan2
- UROC1 | c.1806C>T p.N602= | Silent (SNP) | VAF 186/363 reads (51%) | catalogued as rs138856930, COSV52034016; called by muse, mutect2, varscan2
- CCDC40 | c.2832+406C>T | Intron (SNP) | VAF 167/1214 reads (14%) | catalogued as rs762739933; called by muse, varscan2
- FRAS1 | c.5856+16G>A | Intron (SNP) | VAF 187/407 reads (46%) | called by muse, mutect2, varscan2
- SH3KBP1 | c.1298+37del | Intron (DEL) | VAF 153/431 reads (35%) | called by mutect2, pindel, varscan2
